Somatic mutation profile of tumor specimen TCGA-VS-A8QH-01A (aliquot TCGA-VS-A8QH-01A-11D-A37N-09) from TCGA case TCGA-VS-A8QH, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G2; Age at diagnosis: 76.4 years (27,909 days).
Specimen TCGA-VS-A8QH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2b4a2a4-f077-4de8-ba8c-f7f1ef8ed5d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A8QH-10A (Blood Derived Normal), aliquot TCGA-VS-A8QH-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3dc1a958-1264-4727-9e3b-9783449f24bd

The open-access MAF lists 130 somatic variants for this specimen: 103 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 23, Nonsense Mutation 7, RNA 3, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AUTS2 | c.1483C>T p.R495* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as rs1057517708, COSV100715246, COSV61435162; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.490A>G p.K164E | Missense Mutation (SNP) | VAF 21/37 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs879254249, COSV52676020, COSV52700231, COSV52728094, COSV52766542; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK2 | c.6271G>A p.V2091I | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); catalogued as rs760059236, COSV100864165, COSV64490016; called by muse, mutect2, varscan2
- ANKRD17 | c.3757A>T p.N1253Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100428634; called by muse, mutect2, varscan2
- ARSD | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99471992; called by muse, mutect2, varscan2
- ATG4C | c.1134G>T p.M378I | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100507882; called by muse, mutect2, varscan2
- ATR | c.4555A>T p.K1519* | Nonsense Mutation (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100637738; called by muse, mutect2, varscan2
- BBX | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs761415898, COSV57883689; called by muse, mutect2, varscan2
- C12orf56 | c.1067A>C p.K356T (on ENST00000543942 / NM_001170633.2; = p.K196T on NM_001099676.3) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as rs1404186142, COSV100399085; called by muse, mutect2, varscan2
- CADPS | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs758477480, COSV51879470; called by muse, mutect2, varscan2
- CAMKV | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV99615167; called by muse, mutect2, varscan2
- CCDC148 | c.1166C>T p.S389F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51757693, COSV51761422, COSV99319812; called by muse, varscan2
- CNTLN | c.1538C>A p.S513* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99263051; called by muse, mutect2, varscan2
- COL5A3 | c.4880C>A p.P1627Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV99318305; called by muse, mutect2
- COL6A1 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs564072783, COSV100719981; called by muse, mutect2, varscan2
- COL6A3 | c.3575G>A p.R1192H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs776312405, COSV99796426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPEB1 | c.1472C>T p.T491M (on ENST00000617958; = p.T426M on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375054209; called by muse, mutect2, varscan2
- CTAGE6 | c.1370C>A p.S457Y | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.851); catalogued as COSV101417811, COSV101417842; called by muse, mutect2, varscan2
- CYP2U1 | c.1345G>C p.V449L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100256618; called by muse, mutect2, varscan2
- DDX58 | c.1569C>A p.F523L | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101152530; called by muse, mutect2, varscan2
- DEFB113 | c.158A>C p.Y53S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV100435365; called by muse, mutect2, varscan2
- EFEMP1 | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.079); catalogued as rs573326655, COSV62615614; called by muse, mutect2, varscan2
- EIF3A | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100974509; called by muse, mutect2, varscan2
- ENTHD1 | c.263A>C p.K88T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV104412813, COSV57319807; called by muse, mutect2, varscan2
- ERBIN | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 7/30 reads (23%) | catalogued as COSV99396046; called by muse, mutect2, varscan2
- ERBIN | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52319465; called by muse, mutect2, varscan2
- FASTKD3 | c.1623G>C p.K541N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV99242427; called by muse, mutect2, varscan2
- FBXW7 | c.1946G>A p.W649* (on ENST00000281708 / NM_001349798.2; = p.W569* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | catalogued as COSV99654862; called by muse, mutect2, varscan2
- FGF14 | c.719C>A p.P240Q | Missense Mutation (SNP) | VAF 65/145 reads (45%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.131); catalogued as COSV101084910; called by muse, mutect2, varscan2
- FRYL | c.1912G>A p.V638I | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.393); catalogued as rs562863114, COSV99976040; called by mutect2, varscan2
- FSCN1 | c.1423G>A p.A475T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV100435034; called by muse, mutect2
- GCSAML | c.241T>A p.S81T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV63578643; called by muse, mutect2, varscan2
- GDNF | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320256760, COSV58479582; called by muse, mutect2, varscan2
- GLYR1 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.329); catalogued as COSV100424084; called by muse, mutect2, varscan2
- GRIA3 | c.1579A>C p.S527R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99989183; called by muse, mutect2, varscan2
- GRIK2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.356); catalogued as rs778896944, COSV59711603, COSV59784402; called by muse, mutect2, varscan2
- HNRNPUL2 | c.2015C>T p.A672V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.935); catalogued as COSV100079422; called by muse, mutect2, varscan2
- HSF2 | c.376T>A p.L126I | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as rs765283128, COSV100869648; called by muse, mutect2
- HSF2 | c.378A>C p.L126F | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100869649; called by muse, mutect2
- IQSEC3 | c.119A>G p.E40G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV100406888; called by mutect2, varscan2
- IRX5 | c.530T>C p.M177T | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100315652; called by muse, mutect2, varscan2
- KCTD10 | c.657G>C p.Q219H | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV57326587, COSV99949069; called by muse, mutect2, varscan2
- KDM1A | c.2354C>G p.S785W | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV56500387; called by muse, mutect2, varscan2
- LAMA2 | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101370183, COSV70356939; called by muse, mutect2, varscan2
- MAGI2 | c.343C>T p.R115* | Nonsense Mutation (SNP) | VAF 13/57 reads (23%) | catalogued as rs199541452, COSV62678542; called by muse, mutect2, varscan2
- MAMDC2 | c.818A>C p.E273A | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101015269; called by muse, mutect2, varscan2
- MAP3K1 | c.2090G>A p.R697H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1305030339, COSV68121625, COSV68124440; called by muse, mutect2, varscan2
- MAP7D2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs774743082, COSV65528270; called by muse, mutect2, varscan2
- MIA2 | c.59G>T p.R20L | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as rs777045235, COSV99697357; called by muse, mutect2, varscan2
- NCOR1 | c.5263C>T p.R1755C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51965417; called by muse, mutect2, varscan2
- NF2 | c.1123-1G>T p.X375_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100097638, COSV58525634; called by muse, mutect2, varscan2
- NISCH | c.2283T>A p.F761L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100617163; called by muse, mutect2, varscan2
- NLRP7 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765446538, COSV100052239, COSV60170834; called by muse, mutect2, varscan2
- NOS1 | c.2918A>T p.K973M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100500128; called by muse, mutect2, varscan2
- NRK | c.2221G>C p.E741Q | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99686755, COSV99686837; called by muse, mutect2, varscan2
- NUP160 | c.2947G>T p.A983S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101021342; called by muse, mutect2, varscan2
- OLFM4 | c.242G>A p.G81E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as COSV54577591, COSV99524549; called by muse, mutect2, varscan2
- OR2B6 | c.431T>G p.L144W | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99773642; called by muse, mutect2, varscan2
- OR5J2 | c.68T>G p.L23R | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100398920; called by muse, mutect2, varscan2
- PARD6B | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.281); catalogued as COSV100859872; called by muse, mutect2, varscan2
- PBLD | c.299C>T p.T100M | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs750680281, COSV53266398; called by muse, mutect2, varscan2
- PCDHA1 | c.1742T>C p.V581A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.35); catalogued as COSV65373557; called by mutect2, varscan2
- PLA2G6 | c.1741A>G p.K581E | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100140240; called by muse, mutect2, varscan2
- POLM | c.1247G>T p.R416I | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99641676; called by muse, mutect2, varscan2
- PRG2 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as rs375145993; called by muse, mutect2, varscan2
- PRKCQ | c.1988A>G p.N663S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54108641; called by muse, mutect2
- PRKDC | c.5659G>C p.D1887H | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100038730, COSV100040776; called by muse, mutect2, varscan2
- RADX | c.2515A>T p.N839Y | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); catalogued as COSV100998760; called by muse, mutect2, varscan2
- RALGDS | c.2535C>A p.D845E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as COSV100924287; called by muse, mutect2, varscan2
- RANBP2 | c.6755C>G p.P2252R | Missense Mutation (SNP) | VAF 7/188 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV99311375; called by muse, mutect2
- RASA3 | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 59/117 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863639; called by muse, mutect2, varscan2
- RASSF9 | c.227A>G p.D76G | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.517); catalogued as rs1008059188, COSV100771228; called by muse, mutect2, varscan2
- RGS7BP | c.403T>C p.Y135H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100470471; called by muse, mutect2
- RICTOR | c.2014G>T p.G672* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99704453; called by muse, mutect2, varscan2
- RIMS2 | c.3269A>T p.Q1090L (on ENST00000666250 / NM_001348490.2; = p.Q898L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.814); catalogued as COSV99163145; called by muse, mutect2, varscan2
- ROBO2 | c.3171C>G p.N1057K | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100164633; called by muse, mutect2, varscan2
- ROS1 | c.7027G>A p.G2343R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV100876572; called by muse, mutect2, varscan2
- SEMA4B | c.2029G>C p.D677H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV100153231; called by muse, mutect2, varscan2
- SIRPB2 | c.212T>C p.I71T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as rs1296689395, COSV100708404; called by muse, mutect2, varscan2
- SLC35A2 | c.444G>T p.K148N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504076; called by muse, mutect2, varscan2
- SLC6A19 | c.1016+1G>A p.X339_splice | Splice Site (SNP) | VAF 6/34 reads (18%) | catalogued as rs568073644, COSV100443272; called by muse, mutect2, varscan2
- SLC6A2 | c.1214C>T p.A405V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as COSV99573414; called by muse, mutect2, varscan2
- SNTA1 | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99458572; called by muse, mutect2, varscan2
- SORCS1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99543855; called by muse, mutect2, varscan2
- SPAG17 | c.5295G>A p.M1765I | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100308171; called by muse, mutect2, varscan2
- SPTA1 | c.2770A>G p.N924D | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.932); catalogued as rs748301046, COSV100934439; called by muse, mutect2, varscan2
- TAMALIN | c.332C>A p.T111N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs779961496, COSV99531015; called by muse, mutect2, varscan2
- TENM2 | c.7918C>T p.R2640C (on ENST00000518659 / NM_001122679.2; = p.R2401C on NM_001080428.3) | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs1209562198, COSV101318024; called by muse, mutect2, varscan2
- TNR | c.2313C>G p.F771L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as COSV99687985; called by muse, mutect2, varscan2
- TSPYL5 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.347); catalogued as rs1406875500, COSV59072804; called by muse, mutect2
- UACA | c.3875G>A p.R1292Q | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768309300, COSV59854989; called by muse, mutect2, varscan2
- VPS53 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.143); catalogued as rs774768457, COSV99345475; called by muse, mutect2, varscan2
- ZMAT4 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs1419897637, COSV52695626; called by muse, mutect2, varscan2
- ZMYND12 | c.917C>A p.T306N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs201018230; called by muse, mutect2, varscan2
- ZNF256 | c.1432C>G p.L478V | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as COSV99990650; called by muse, mutect2, varscan2
- ZNF766 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as COSV100765268; called by muse, mutect2, varscan2
- FIGNL2 | c.178C>G p.L60V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GPR42 | c.184C>A p.L62M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIR3DL2 | c.466C>G p.H156D | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- MFN1 | c.1863G>T p.M621I | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2
- RBMX2 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TPTE | c.449G>A p.R150K (on ENST00000618007 / NM_199261.4; = p.R132K on NM_199259.4) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ABCC2 | c.3027C>T p.I1009= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV100966408, COSV64986058; called by muse, mutect2, varscan2
- ANK1 | c.1722C>T p.H574= | Silent (SNP) | VAF 40/271 reads (15%) | catalogued as rs373230864; called by muse, mutect2, varscan2
- C12orf40 | c.36G>C p.L12= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV61129482; called by muse, mutect2, varscan2
- CATIP | c.750C>T p.S250= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs201990286, COSV99179495; called by muse, mutect2, varscan2
- COL27A1 | c.2808G>A p.P936= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as rs753347288, COSV61928867; called by muse, mutect2, varscan2
- DNAH5 | c.6241T>C p.L2081= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99445791; called by muse, mutect2, varscan2
- DOCK2 | c.1146C>A p.T382= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV99910586, COSV99912766; called by muse, mutect2, varscan2
- GTF3C3 | c.735A>G p.K245= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV99826521; called by muse, mutect2, varscan2
- HS6ST2 | c.870C>T p.H290= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs1191622696, COSV100897023; called by muse, mutect2, varscan2
- IGKV3-20 | c.237C>T p.I79= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs751536986; called by muse, mutect2, varscan2
- KCNJ3 | c.54G>A p.S18= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV99715349; called by muse, mutect2, varscan2
- LRRIQ1 | c.1353A>G p.V451= | Silent (SNP) | VAF 29/115 reads (25%) | catalogued as COSV101279623; called by muse, mutect2, varscan2
- MYCBP2 | c.5148T>G p.P1716= (on ENST00000357337; = p.P1754= on NM_015057.5) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100629340; called by muse, mutect2, varscan2
- PAX3 | c.492A>G p.K164= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs769266836, COSV99286429; called by muse, mutect2, varscan2
- PTDSS2 | c.606T>G p.L202= | Silent (SNP) | VAF 27/67 reads (40%) | catalogued as rs150004332, COSV100339042; called by muse, mutect2, varscan2
- RBM47 | c.195G>A p.P65= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs769060213, COSV55934013; called by muse, mutect2, varscan2
- REM1 | c.291C>A p.A97= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99146783; called by muse, mutect2, varscan2
- RGS22 | c.630A>G p.L210= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs750925608, COSV100693019; called by muse, mutect2, varscan2
- SH2D3A | c.696C>T p.C232= | Silent (SNP) | VAF 27/99 reads (27%) | catalogued as rs199547986, COSV99837835; called by muse, mutect2, varscan2
- SLC6A3 | c.1674C>T p.N558= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs138872678; called by muse, mutect2, varscan2
- SPATA31A1 | c.1779T>G p.P593= | Silent (SNP) | VAF 14/64 reads (22%) | called by mutect2, varscan2
- TOP2A | c.4215T>A p.I1405= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV101352289; called by muse, mutect2, varscan2
- TRIM22 | c.537G>A p.E179= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV101181225; called by muse, mutect2, varscan2
- PKD1L2 | n.700C>T | RNA (SNP) | VAF 11/59 reads (19%) | catalogued as rs539451747; called by muse, mutect2, varscan2
- PRKN | c.1083+3438T>C | Intron (SNP) | VAF 24/53 reads (45%) | catalogued as COSV100627650; called by muse, mutect2, varscan2
- SSPOP | n.8728G>A | RNA (SNP) | VAF 14/34 reads (41%) | catalogued as rs780497274, COSV100947046; called by muse, mutect2, varscan2
- ZNF322P1 | n.319A>T | RNA (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
